Somatic mutation profile of tumor specimen TARGET-30-PARVNT-01A (aliquot TARGET-30-PARVNT-01A-01D) from TARGET case TARGET-30-PARVNT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.8 years (2,487 days).
Specimen TARGET-30-PARVNT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8c65bd4-39b7-44bc-9f77-91e7e59056df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARVNT-10A (Blood Derived Normal), aliquot TARGET-30-PARVNT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6561d5e9-4e22-4d5b-b727-ba13c08119b1

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Nonsense Mutation 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 65/93 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP1AR | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as COSV56768742; called by muse, mutect2, varscan2
- C2orf16 | c.4003G>T p.A1335S | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); catalogued as COSV62674473; called by muse, mutect2, varscan2
- CRX | c.709del p.L237Sfs*134 | Frame Shift Del (DEL) | VAF 57/176 reads (32%) | catalogued as rs281865518; ClinVar: not provided; called by mutect2, pindel, varscan2
- CSMD1 | c.4297G>T p.V1433L (on ENST00000520002; = p.V1432L on NM_033225.6) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV59298887; called by muse, mutect2, varscan2
- CYP4B1 | c.699T>A p.N233K | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.292); catalogued as COSV54722000; called by muse, mutect2, varscan2
- FAM187B | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV61201091; called by muse, mutect2, varscan2
- FAM8A1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs1287035427, COSV52580980; called by muse, mutect2, varscan2
- FREM2 | c.4888G>A p.V1630I | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV54832223; called by muse, mutect2, varscan2
- FZD7 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.516); catalogued as COSV53808702; called by muse, mutect2, varscan2
- KANK1 | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV63210234; called by muse, mutect2, varscan2
- KCTD21 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs748855021, COSV60740907; called by muse, mutect2, varscan2
- KIAA1217 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs777651861, COSV64602927; called by muse, mutect2, varscan2
- MS4A1 | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV61941865; called by muse, mutect2, varscan2
- MTCH1 | c.1131C>G p.F377L (on ENST00000373627 / NM_001271641.1; = p.F360L on NM_014341.2) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs750316963, COSV65320108; called by muse, mutect2, varscan2
- OR6Q1 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56932591; called by muse, mutect2, varscan2
- PDE6G | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 140/199 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58507181; called by muse, mutect2, varscan2
- SERPINB12 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV54032514; called by muse, mutect2, varscan2
- SHC3 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs778896913, COSV65437305; called by muse, mutect2, varscan2
- SHFL | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53461691; called by muse, mutect2, varscan2
- SLC1A4 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV52234009; called by mutect2, varscan2
- SUGP2 | c.2794G>A p.D932N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs745321110, COSV58256585; called by muse, mutect2, varscan2
- USP8 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV56163282; called by muse, mutect2, varscan2
- XPC | c.59A>T p.K20I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV53204139; called by muse, mutect2, varscan2
- FAT3 | c.11647A>C p.I3883L | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ADCK5 | c.1131G>A p.E377= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs932523960, COSV58232800; called by muse, mutect2, varscan2
- ARHGAP45 | c.1839A>C p.G613= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV57430385; called by muse, mutect2, varscan2
- DMXL1 | c.3123T>G p.T1041= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV60707562; called by muse, mutect2, varscan2
- DRG2 | c.870C>T p.T290= | Silent (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- PCSK1 | c.1938C>A p.P646= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- SIGLEC8 | c.954G>T p.V318= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58471692; called by muse, mutect2, varscan2
- UROC1 | c.522C>T p.L174= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs1216281433, COSV52030975; called by muse, mutect2, varscan2
- CSNK1E | c.886-2077G>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- ELMOD3 | c.943+125G>C | Intron (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
